Somatic mutation profile of tumor specimen TARGET-30-PANRVJ-01A (aliquot TARGET-30-PANRVJ-01A-01D) from TARGET case TARGET-30-PANRVJ, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 13.1 years (4,781 days).
Specimen TARGET-30-PANRVJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce1630c0-6cfc-4e51-8471-aaf250abb8c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANRVJ-10A (Blood Derived Normal), aliquot TARGET-30-PANRVJ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3df804cc-1634-402a-9ba8-cb2796f65f7e

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Splice Site 2, 5'Flank 1, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3520T>A p.F1174I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs281864719, CM113795, COSV66556166, COSV66559314, COSV66568713; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP5S1 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55694524; called by muse, mutect2, varscan2
- ATRX | c.6589C>T p.R2197C | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64873999; called by muse, mutect2, varscan2
- INPP5D | c.2390T>A p.L797Q (on ENST00000445964 / NM_001017915.3; = p.L796Q on NM_005541.5) | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64039337; called by muse, mutect2, varscan2
- MCF2L | c.2446G>A p.A816T (on ENST00000375608; = p.A784T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs763829216, COSV56180386; called by muse, mutect2, varscan2
- MPRIP | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs771851390, COSV57929633; called by muse, mutect2, varscan2
- STK38L | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1198858335; called by muse, mutect2
- ALYREF | c.491del p.A164Efs*4 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- LRIG3 | c.803+1del p.X268_splice | Splice Site (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- PASK | c.430-2A>C p.X144_splice | Splice Site (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- H2BC8 | c.51G>A p.K17= | Silent (SNP) | VAF 49/219 reads (22%) | catalogued as rs1354989060, COSV55127533; called by muse, mutect2, varscan2
- SUCO | chr1:172532630 G>A | 5'Flank (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
